CCDI case PBCMZY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/dee0e421-1136-4ef6-97c6-6900e758de32

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 8240/3; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 15.6 years (5,681 days).

Biospecimens (2 samples)
- Sample 0DVKG8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVKGA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
